Somatic mutation profile of tumor specimen 0DBQFD from CCDI case PBBLNU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 8.2 years (3,007 days).
Specimen 0DBQFD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1aaaafae-921b-47dd-806d-2c97433617e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBQF9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6221bef-5511-43d0-ba4f-4c9414b7d22b

The open-access MAF lists 29 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 7, Intron 6, Nonsense Mutation 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 237/529 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BECN1 | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 197/537 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as rs368727081; called by muse, mutect2, varscan2
- COPS3 | c.362T>G p.I121S | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV52007085; called by muse, mutect2, varscan2
- CPEB1 | c.1175G>A p.R392H (on ENST00000617958; = p.R332H on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 376/806 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs754687553; called by muse, mutect2, varscan2
- MAGEA4 | c.663A>T p.E221D | Missense Mutation (SNP) | VAF 124/149 reads (83%) | SIFT tolerated (0.44); PolyPhen benign (0.088); catalogued as COSV52341393; called by muse, mutect2, varscan2
- MUC5AC | c.5347C>T p.R1783* | Nonsense Mutation (SNP) | VAF 125/783 reads (16%) | catalogued as rs1448583826; called by muse, mutect2, varscan2
- MUC5AC | c.6466C>T p.R2156* | Nonsense Mutation (SNP) | VAF 96/695 reads (14%) | catalogued as rs1208391108; called by muse, mutect2, varscan2
- NLGN4X | c.2138C>A p.P713H | Missense Mutation (SNP) | VAF 227/487 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52014296, COSV99323854; called by muse, mutect2, varscan2
- OBSCN | c.12217C>T p.R4073W | Missense Mutation (SNP) | VAF 137/527 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369660432; called by muse, mutect2, varscan2
- REM2 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 257/567 reads (45%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs773368193, COSV57465117; called by muse, mutect2, varscan2
- DDX46 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 389/924 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MUC3A | c.7372G>T p.A2458S | Missense Mutation (SNP) | VAF 159/379 reads (42%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- SLC12A4 | c.313G>A p.G105R | Missense Mutation (SNP) | VAF 192/450 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TP53 | c.551_555dup p.D186Ifs*63 | Frame Shift Ins (INS) | VAF 112/264 reads (42%) | called by mutect2, varscan2
- ZNF532 | c.3050C>T p.T1017I | Missense Mutation (SNP) | VAF 282/672 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAGIX | c.126G>A p.A42= | Silent (SNP) | VAF 162/362 reads (45%) | called by muse, mutect2, varscan2
- MNX1 | c.111C>A p.A37= | Silent (SNP) | VAF 184/386 reads (48%) | called by muse, mutect2, varscan2
- NLGN4X | c.2019C>A p.T673= | Silent (SNP) | VAF 343/668 reads (51%) | called by muse, mutect2, varscan2
- NR2F6 | c.480C>T p.L160= | Silent (SNP) | VAF 129/274 reads (47%) | catalogued as rs1396918203; called by muse, mutect2, varscan2
- SPATA31D3 | c.2439T>C p.D813= | Silent (SNP) | VAF 227/772 reads (29%) | catalogued as rs777393942; called by muse, mutect2, varscan2
- TRIM42 | c.780C>T p.N260= | Silent (SNP) | VAF 186/414 reads (45%) | called by muse, mutect2, varscan2
- TTN | c.10245G>A p.T3415= (on ENST00000591111; = p.T3369= on NM_003319.4) | Silent (SNP) | VAF 260/963 reads (27%) | catalogued as rs1208622337, COSV100632018; called by muse, mutect2, varscan2
- CARS1 | c.1479-86C>T | Intron (SNP) | VAF 8/44 reads (18%) | catalogued as rs918541388; called by muse, varscan2
- CWF19L1 | c.505-74A>G | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- FBLN7 | c.670+53C>T | Intron (SNP) | VAF 30/81 reads (37%) | catalogued as rs1332905493, COSV99734891; called by muse, mutect2, varscan2
- GABRD | c.692-99C>T | Intron (SNP) | VAF 10/30 reads (33%) | called by muse, mutect2
- TKTL1 | c.135-61A>G | Intron (SNP) | VAF 74/94 reads (79%) | called by muse, mutect2, varscan2
- TPM1 | c.563+12C>T | Intron (SNP) | VAF 136/329 reads (41%) | catalogued as rs756230680; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSSK6 | c.*10G>T | 3'UTR (SNP) | VAF 94/245 reads (38%) | called by muse, mutect2, varscan2
